Somatic mutation profile of tumor specimen ALCH-AFJT-TTP1-A (aliquot ALCH-AFJT-TTP1-A-3-0-D-A678-36) from ALCHEMIST case ALCH-AFJT, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 71.6 years (26,138 days).
Specimen ALCH-AFJT-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 21fa576c-76d1-4df0-ba91-526a311e92e0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AFJT-NB1-A (Blood Derived Normal), aliquot ALCH-AFJT-NB1-A-1-0-D-A678-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c13db2d8-6d27-4aca-9aa4-e532fcb95b10

The open-access MAF lists 239 somatic variants for this specimen: 161 protein-altering or splice-affecting, 51 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 145, Silent 51, Intron 14, Nonsense Mutation 10, RNA 5, 5'Flank 4, Frame Shift Del 3, 3'UTR 3, Splice Site 2, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 17/149 reads (11%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4420G>A p.E1474K | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.574); catalogued as rs758023079; called by muse, mutect2, varscan2
- ARHGAP17 | c.1712C>G p.P571R | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.01); catalogued as rs1269054895, COSV51511143; called by muse, mutect2, varscan2
- BRIP1 | c.3344C>A p.S1115Y | Missense Mutation (SNP) | VAF 68/383 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as rs1419933310, COSV99369002; called by muse, mutect2, varscan2
- C1S | c.514G>A p.G172R | Missense Mutation (SNP) | VAF 26/435 reads (6%) | SIFT tolerated (0.64); PolyPhen benign (0.112); catalogued as rs375308014; ClinVar: uncertain significance; called by muse, mutect2
- CACNA1G | c.2047C>A p.R683S | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376301818; called by muse, mutect2, varscan2
- CACNA1I | c.4724C>T p.A1575V | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs560099596; called by muse, mutect2, varscan2
- CD1C | c.611-1G>T p.X204_splice | Splice Site (SNP) | VAF 5/35 reads (14%) | catalogued as COSV63806014; called by muse, varscan2
- CFAP47 | c.7319C>T p.A2440V | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV101074542; called by muse, varscan2
- CHRM3 | c.1358C>A p.T453N | Missense Mutation (SNP) | VAF 29/183 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.088); catalogued as COSV55095146; called by muse, mutect2, varscan2
- CRYGA | c.139G>C p.E47Q | Missense Mutation (SNP) | VAF 26/217 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs1274763610; called by muse, mutect2, varscan2
- CSMD1 | c.4373G>T p.G1458V (on ENST00000520002; = p.G1457V on NM_033225.6) | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59312146, COSV59381927; called by muse, mutect2, varscan2
- CTNNB1 | c.1274C>A p.S425Y | Missense Mutation (SNP) | VAF 22/418 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100846423; called by muse, mutect2
- CWC22 | c.1530A>T p.L510F | Missense Mutation (SNP) | VAF 30/299 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1366380912; called by muse, mutect2, varscan2
- CYP11B2 | c.1037C>A p.A346D | Missense Mutation (SNP) | VAF 29/188 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.457); catalogued as COSV59996901; called by muse, mutect2, varscan2
- CYP2D7 | c.29C>A p.A10D | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100809485; called by muse, varscan2
- CYRIB | c.199A>G p.I67V | Missense Mutation (SNP) | VAF 66/500 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101310351; called by muse, varscan2
- DCC | c.2304C>A p.Y768* | Nonsense Mutation (SNP) | VAF 44/245 reads (18%) | catalogued as COSV100502059; called by muse, mutect2, varscan2
- DYNC2LI1 | c.513T>G p.H171Q | Missense Mutation (SNP) | VAF 37/343 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs771678612; called by muse, mutect2, varscan2
- EPOR | c.1249G>T p.E417* | Nonsense Mutation (SNP) | VAF 16/217 reads (7%) | catalogued as CM105097; called by muse, mutect2
- FRMPD3 | c.803A>G p.K268R | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as rs1250490537; called by muse, mutect2, varscan2
- GABRA6 | c.34C>A p.L12M | Missense Mutation (SNP) | VAF 83/539 reads (15%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.372); catalogued as rs749514674; called by muse, mutect2, varscan2
- IGHM | c.1351G>A p.A451T | Missense Mutation (SNP) | VAF 16/248 reads (6%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.691); catalogued as rs751188409; called by muse, mutect2
- IKZF3 | c.1186C>T p.R396C | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs748446589, COSV53099754; called by muse, mutect2, varscan2
- JADE2 | c.2135G>T p.R712L | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as rs371350576, COSV104391135; called by muse, mutect2, varscan2
- KRTAP5-6 | c.373T>A p.C125S | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV66289353; called by muse, mutect2, varscan2
- LILRB2 | c.428A>G p.Q143R | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.438); catalogued as rs1334942823; called by muse, mutect2, varscan2
- MGAM2 | c.4236C>A p.S1412R | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs933891965; called by muse, mutect2
- MYPN | c.3152C>T p.S1051F | Missense Mutation (SNP) | VAF 38/374 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV62731535, COSV62739679; called by muse, mutect2, varscan2
- NDEL1 | c.977C>T p.P326L | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.028); catalogued as COSV55330963; called by muse, mutect2, varscan2
- NEDD4 | c.2967G>T p.K989N (on ENST00000508342 / NM_001284338.1; = p.K570N on NM_006154.4) | Missense Mutation (SNP) | VAF 62/674 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100164136; called by muse, mutect2
- NRCAM | c.2896G>T p.D966Y (on ENST00000379028 / NM_001371124.1; = p.D950Y on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/232 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV100694219; called by muse, mutect2
- NXPE4 | c.1345C>T p.R449* (on ENST00000375478 / NM_001077639.2; = p.R165* on NM_017678.3) | Nonsense Mutation (SNP) | VAF 18/159 reads (11%) | catalogued as rs750280300, COSV100970298, COSV64943495; called by muse, mutect2, varscan2
- OR10S1 | c.890T>C p.L297P | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV73342659; called by muse, mutect2, varscan2
- OR1C1 | c.768C>G p.I256M | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.973); catalogued as rs267598481, COSV68715593; called by muse, mutect2, varscan2
- OSBPL3 | c.2194G>A p.A732T | Missense Mutation (SNP) | VAF 31/256 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as rs570310665; called by muse, mutect2, varscan2
- PKHD1L1 | c.5826G>T p.E1942D | Missense Mutation (SNP) | VAF 54/360 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101006547; called by muse, mutect2, varscan2
- POM121L12 | c.167G>A p.R56K | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.89); PolyPhen benign (0.026); catalogued as COSV68693556; called by muse, mutect2, varscan2
- PPM1B | c.559G>A p.V187M | Missense Mutation (SNP) | VAF 48/375 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1255542646, COSV56766989; called by muse, mutect2, varscan2
- REG4 | c.235A>G p.I79V | Missense Mutation (SNP) | VAF 15/261 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs1328793386; called by muse, mutect2
- RILPL1 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1566117357, COSV61552592; called by muse, mutect2
- RTN4RL1 | c.835G>T p.A279S | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV58675895; called by muse, mutect2, varscan2
- RYR3 | c.9205A>G p.T3069A (on ENST00000389232; = p.T3070A on NM_001036.6) | Missense Mutation (SNP) | VAF 18/225 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV66810263; called by muse, mutect2
- SATB2 | c.1699C>A p.R567S | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.585); catalogued as COSV53484717; called by muse, mutect2, varscan2
- SCIN | c.1415G>T p.R472L (on ENST00000297029 / NM_001112706.3; = p.R225L on NM_033128.3) | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs757373352; called by muse, mutect2
- SFMBT2 | c.128G>T p.G43V | Missense Mutation (SNP) | VAF 38/363 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.513); catalogued as rs1463605866; called by muse, mutect2
- SLC18B1 | c.1267G>T p.G423C | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as COSV51594497; called by muse, mutect2
- SNRNP70 | c.490G>T p.A164S | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); catalogued as COSV55506002; called by muse, mutect2, varscan2
- SPEF2 | c.5056G>C p.E1686Q | Missense Mutation (SNP) | VAF 122/331 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.255); catalogued as rs766250986; called by muse, mutect2, varscan2
- SPHKAP | c.2306C>G p.S769C | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as rs144775838, COSV60882149; called by muse, mutect2, varscan2
- SV2A | c.481C>T p.H161Y | Missense Mutation (SNP) | VAF 24/242 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64965198; called by muse, mutect2
- TECRL | c.67C>G p.R23G | Missense Mutation (SNP) | VAF 34/354 reads (10%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.099); catalogued as COSV67089273; called by muse, mutect2
- TIAM1 | c.2054C>A p.S685Y | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); catalogued as COSV99733162; called by muse, mutect2, varscan2
- TSEN54 | c.439G>T p.D147Y | Missense Mutation (SNP) | VAF 13/214 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.284); catalogued as rs1179159490; called by muse, mutect2
- TTN | c.44252C>G p.A14751G (on ENST00000591111; = p.A7327G on NM_003319.4) | Missense Mutation (SNP) | VAF 78/667 reads (12%) | PolyPhen probably damaging (0.996); catalogued as COSV104415643; called by muse, mutect2, varscan2
- USH2A | c.12622G>T p.D4208Y | Missense Mutation (SNP) | VAF 29/225 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.402); catalogued as COSV56412301; called by muse, mutect2, varscan2
- ZFHX3 | c.6791A>T p.N2264I | Missense Mutation (SNP) | VAF 34/301 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV51712714; called by muse, mutect2, varscan2
- ZFHX4 | c.4111C>G p.P1371A | Missense Mutation (SNP) | VAF 32/433 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV50511578; called by muse, mutect2
- ZNF446 | c.724C>T p.H242Y | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as rs756304563; called by muse, mutect2, varscan2
- ZNF804A | c.809G>T p.S270I | Missense Mutation (SNP) | VAF 31/203 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as COSV100167537; called by muse, mutect2, varscan2
- ABCC3 | c.1133G>T p.G378V | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); called by muse, mutect2
- ADGRB3 | c.4373G>C p.S1458T | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, varscan2
- ADGRG4 | c.2878C>A p.H960N | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- AIRE | c.1517G>T p.S506I | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- ANGPTL5 | c.59G>T p.G20V | Missense Mutation (SNP) | VAF 37/337 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- ANK2 | c.6334A>T p.K2112* | Nonsense Mutation (SNP) | VAF 17/157 reads (11%) | called by muse, mutect2, varscan2
- ANTXR1 | c.1055A>T p.K352M | Missense Mutation (SNP) | VAF 49/384 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- CACNA1G | c.2046C>A p.D682E | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CARD14 | c.2242C>T p.L748F | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- CASP12 | c.581C>T p.T194I | Missense Mutation (SNP) | VAF 46/396 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- CHRNB2 | c.1344T>G p.S448R | Missense Mutation (SNP) | VAF 27/222 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CLDN1 | c.317A>C p.K106T | Missense Mutation (SNP) | VAF 61/395 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- CNTNAP5 | c.2633G>C p.R878P | Missense Mutation (SNP) | VAF 33/449 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); called by muse, mutect2
- COL4A3 | c.1883G>A p.G628D | Missense Mutation (SNP) | VAF 34/304 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD1 | c.3067T>A p.F1023I (on ENST00000520002; = p.F1022I on NM_033225.6) | Missense Mutation (SNP) | VAF 42/366 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CSMD2 | c.3988G>A p.D1330N | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- DCAF5 | c.2123A>C p.K708T | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2
- DLG5 | c.3700G>T p.D1234Y | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- DNAH6 | c.2638G>A p.E880K | Missense Mutation (SNP) | VAF 29/231 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- DNAH7 | c.5755G>T p.V1919F | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DNAJC22 | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- DPP4 | c.367C>T p.Q123* | Nonsense Mutation (SNP) | VAF 25/233 reads (11%) | called by muse, mutect2, varscan2
- FSIP2 | c.7727C>A p.S2576Y | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- FUCA1 | c.518G>T p.R173L | Missense Mutation (SNP) | VAF 38/374 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- GATC | c.166C>G p.R56G | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.645); called by muse, mutect2
- GLYAT | c.206T>A p.L69H | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); called by muse, mutect2
- GRM4 | c.2305G>T p.V769L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- GRM5 | c.1153C>A p.L385M | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.086); called by muse, mutect2
- HERC5 | c.671G>A p.G224D | Missense Mutation (SNP) | VAF 15/182 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HSPA4L | c.685C>G p.P229A | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.887); called by muse, mutect2
- IBTK | c.3740G>C p.G1247A | Missense Mutation (SNP) | VAF 40/380 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.079); called by muse, mutect2
- IBTK | c.109C>G p.L37V | Missense Mutation (SNP) | VAF 11/399 reads (3%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2
- IGKV2D-28 | c.331T>C p.Y111H | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); called by mutect2, varscan2
- IL12A | c.739A>G p.M247V | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- INO80D | c.2080T>G p.S694A | Missense Mutation (SNP) | VAF 28/223 reads (13%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ITPR1 | c.846G>A p.W282* | Nonsense Mutation (SNP) | VAF 33/157 reads (21%) | called by muse, mutect2, varscan2
- IZUMO3 | c.496G>T p.D166Y (on ENST00000543880 / NM_001365008.2; = p.D160Y on NM_001271706.1) | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- JAK1 | c.1361G>T p.R454L | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- KIF13A | c.4457G>A p.R1486K | Missense Mutation (SNP) | VAF 25/199 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KRT28 | c.664A>G p.T222A | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRP1B | c.11187C>A p.C3729* | Nonsense Mutation (SNP) | VAF 40/401 reads (10%) | called by muse, mutect2
- LRRC53 | c.1181C>G p.T394S | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MAMDC2 | c.139A>T p.N47Y | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- MAP2K3 | c.227G>T p.G76V (on ENST00000342679 / NM_145109.3; = p.G47V on NM_002756.4) | Missense Mutation (SNP) | VAF 10/246 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MME | c.1616C>A p.A539E | Missense Mutation (SNP) | VAF 52/464 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MROH8 | c.728G>T p.R243L | Missense Mutation (SNP) | VAF 38/321 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- MSH4 | c.1972T>G p.S658A | Missense Mutation (SNP) | VAF 42/339 reads (12%) | SIFT tolerated (0.67); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MVK | c.1151C>A p.S384Y | Missense Mutation (SNP) | VAF 15/184 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); called by muse, mutect2
- MYH8 | c.434A>G p.Y145C | Missense Mutation (SNP) | VAF 44/286 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- MYLK2 | c.886T>G p.F296V | Missense Mutation (SNP) | VAF 39/284 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NCOA2 | c.2798G>T p.G933V | Missense Mutation (SNP) | VAF 25/173 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NKAIN3 | c.380T>C p.M127T | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NPHP4 | c.3577del p.D1193Tfs*4 | Frame Shift Del (DEL) | VAF 12/102 reads (12%) | called by mutect2, pindel, varscan2
- NUDT16 | c.93C>A p.D31E | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- OR10G7 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR2L8 | c.260del p.G87Efs*20 | Frame Shift Del (DEL) | VAF 46/384 reads (12%) | called by mutect2, varscan2
- OR51M1 | c.682C>A p.L228M | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.7); called by muse, mutect2
- OR5D14 | c.277A>T p.S93C | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2
- OR5H6 | c.523C>A p.H175N (on ENST00000642105; = p.H159N on NM_001005479.2) | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- OR6N2 | c.643A>T p.M215L | Missense Mutation (SNP) | VAF 28/272 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR6T1 | c.347C>A p.A116D | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2
- PABPC5 | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- PARPBP | c.965G>A p.G322D | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- PCDHA3 | c.1417C>T p.H473Y | Missense Mutation (SNP) | VAF 56/306 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- PNPT1 | c.128G>T p.G43V | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.02); called by muse, mutect2
- PRKG2 | c.776G>T p.R259L | Missense Mutation (SNP) | VAF 26/262 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PSEN1 | c.754G>T p.V252L | Missense Mutation (SNP) | VAF 26/326 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.519); called by muse, mutect2
- PSMC2 | c.1222G>C p.D408H | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RET | c.283C>T p.L95F | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- RGS7 | c.1088G>T p.W363L | Missense Mutation (SNP) | VAF 28/371 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- RNF175 | c.946G>T p.G316* | Nonsense Mutation (SNP) | VAF 19/330 reads (6%) | called by muse, mutect2
- ROPN1B | c.464G>C p.R155P | Missense Mutation (SNP) | VAF 120/436 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- RTN4R | c.1137C>G p.I379M | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- RYR2 | c.3140dup p.D1048Gfs*57 | Frame Shift Ins (INS) | VAF 24/217 reads (11%) | called by mutect2, pindel, varscan2
- SLC6A19 | c.1340G>A p.R447K | Missense Mutation (SNP) | VAF 17/212 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SLCO5A1 | c.2387C>A p.P796Q | Missense Mutation (SNP) | VAF 32/255 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- SOWAHA | c.558G>T p.R186S | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SPANXN3 | c.323C>T p.P108L | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.385); called by muse, mutect2
- STXBP5L | c.2551C>T p.P851S | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- TBC1D30 | c.1570G>T p.E524* (on ENST00000542120; = p.E361* on NM_015279.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 54/346 reads (16%) | called by muse, mutect2, varscan2
- TBXT | c.379C>A p.P127T | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TEKT3 | c.1368G>T p.E456D | Missense Mutation (SNP) | VAF 38/360 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- THSD7A | c.3101C>T p.S1034L | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TJAP1 | c.296A>G p.Q99R | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- TMEM132C | c.2319G>C p.M773I | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.2); called by muse, mutect2
- TNKS | c.3482G>T p.R1161L | Missense Mutation (SNP) | VAF 24/234 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- TOGARAM1 | c.5012G>T p.G1671V | Missense Mutation (SNP) | VAF 26/436 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2
- TP53 | c.629_671del p.N210Rfs*23 | Frame Shift Del (DEL) | VAF 44/325 reads (14%) | called by mutect2, pindel
- TRIM10 | c.1177G>C p.E393Q | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TRIM66 | c.421A>C p.K141Q | Missense Mutation (SNP) | VAF 20/300 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- TTN | c.83444C>G p.T27815R (on ENST00000591111; = p.T20391R on NM_003319.4) | Missense Mutation (SNP) | VAF 48/464 reads (10%) | PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- USP49 | c.295C>G p.L99V | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VWA5A | c.1464G>C p.Q488H | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.662); called by muse, mutect2
- ZIC1 | c.257T>G p.V86G | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ZNF160 | c.2008A>G p.I670V | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.487); called by muse, mutect2
- ZNF416 | c.951C>A p.H317Q | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF621 | c.152-1G>T p.X51_splice | Splice Site (SNP) | VAF 13/56 reads (23%) | called by muse, mutect2, varscan2
- ZNF674 | c.1604G>C p.S535T | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ZNF804A | c.2602A>T p.N868Y | Missense Mutation (SNP) | VAF 44/327 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- ZNF804B | c.442C>G p.Q148E | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- ZNF852 | c.1420A>T p.K474* | Nonsense Mutation (SNP) | VAF 15/150 reads (10%) | called by muse, mutect2, varscan2
- ACAN | c.4395G>C p.G1465= | Silent (SNP) | VAF 31/306 reads (10%) | catalogued as COSV61360659; called by muse, mutect2, varscan2
- ADAMTS12 | c.1686C>T p.V562= | Silent (SNP) | VAF 9/91 reads (10%) | called by muse, mutect2, varscan2
- AK7 | c.975C>T p.V325= | Silent (SNP) | VAF 11/62 reads (18%) | called by muse, mutect2, varscan2
- ATXN7 | c.289C>T p.L97= | Silent (SNP) | VAF 19/296 reads (6%) | called by muse, mutect2
- C16orf95 | c.231C>T p.C77= | Silent (SNP) | VAF 13/118 reads (11%) | called by muse, mutect2, varscan2
- CDH10 | c.810C>A p.P270= | Silent (SNP) | VAF 25/102 reads (25%) | catalogued as COSV52589080, COSV52598240; called by muse, mutect2
- CHTOP | c.207A>G p.L69= | Silent (SNP) | VAF 30/253 reads (12%) | called by muse, mutect2, varscan2
- COL11A1 | c.2662C>A p.R888= | Silent (SNP) | VAF 38/692 reads (5%) | catalogued as COSV62201579; called by muse, mutect2
- COLEC12 | c.765G>T p.T255= | Silent (SNP) | VAF 16/108 reads (15%) | called by muse, mutect2, varscan2
- COLGALT1 | c.888C>T p.R296= | Silent (SNP) | VAF 14/178 reads (8%) | catalogued as rs146222720; called by muse, mutect2
- CSMD3 | c.10077G>C p.R3359= (on ENST00000297405 / NM_001363185.1; = p.R3190= on NM_052900.3) | Silent (SNP) | VAF 156/783 reads (20%) | called by muse, mutect2, varscan2
- CUX2 | c.1779C>A p.A593= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV99920807; called by muse, mutect2, varscan2
- DNAH6 | c.2991C>A p.S997= | Silent (SNP) | VAF 31/281 reads (11%) | called by muse, mutect2, varscan2
- DNAJC4 | c.112C>T p.L38= | Silent (SNP) | VAF 12/144 reads (8%) | called by muse, mutect2
- EMID1 | c.1200C>G p.L400= | Silent (SNP) | VAF 54/226 reads (24%) | catalogued as rs747943370; called by muse, mutect2, varscan2
- ERICH6B | c.822C>A p.A274= | Silent (SNP) | VAF 22/130 reads (17%) | called by muse, varscan2
- FAM47C | c.918C>A p.L306= | Silent (SNP) | VAF 20/87 reads (23%) | called by muse, mutect2, varscan2
- FLNC | c.3987G>T p.L1329= | Silent (SNP) | VAF 15/135 reads (11%) | called by muse, mutect2, varscan2
- FRAS1 | c.2055G>T p.L685= | Silent (SNP) | VAF 22/190 reads (12%) | called by muse, mutect2, varscan2
- GREM2 | c.333G>A p.K111= | Silent (SNP) | VAF 18/84 reads (21%) | called by muse, mutect2, varscan2
- HPS5 | c.2772G>C p.L924= (on ENST00000349215 / NM_181507.2; = p.L810= on NM_007216.4) | Silent (SNP) | VAF 67/436 reads (15%) | catalogued as rs762501695; called by muse, mutect2, varscan2
- IMPG2 | c.1344A>G p.E448= | Silent (SNP) | VAF 44/348 reads (13%) | called by muse, mutect2, varscan2
- MACF1 | c.2044C>T p.L682= | Silent (SNP) | VAF 13/120 reads (11%) | called by muse, varscan2
- MAGEC1 | c.1530C>A p.P510= | Silent (SNP) | VAF 33/132 reads (25%) | catalogued as COSV99596832; called by muse, mutect2, varscan2
- MARCO | c.1368C>A p.A456= | Silent (SNP) | VAF 28/201 reads (14%) | called by muse, mutect2, varscan2
- MTUS2 | c.466C>A p.R156= | Silent (SNP) | VAF 28/155 reads (18%) | called by muse, mutect2, varscan2
- MYBPC3 | c.777C>T p.A259= | Silent (SNP) | VAF 10/74 reads (14%) | called by muse, mutect2, varscan2
- NAA30 | c.450C>A p.V150= | Silent (SNP) | VAF 13/163 reads (8%) | called by muse, mutect2
- NAV3 | c.2359C>A p.R787= | Silent (SNP) | VAF 29/166 reads (17%) | catalogued as COSV104385164; called by muse, mutect2, varscan2
- NRCAM | c.2895G>C p.L965= (on ENST00000379028 / NM_001371124.1; = p.L949= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 17/231 reads (7%) | called by muse, mutect2
- NWD2 | c.2658G>A p.E886= | Silent (SNP) | VAF 8/255 reads (3%) | called by muse, mutect2
- OR51B2 | c.330A>T p.S110= | Silent (SNP) | VAF 30/301 reads (10%) | called by muse, mutect2, varscan2
- OR5B3 | c.666C>A p.T222= | Silent (SNP) | VAF 20/246 reads (8%) | catalogued as COSV58677546; called by muse, mutect2
- OR6C1 | c.438T>C p.S146= | Silent (SNP) | VAF 20/416 reads (5%) | catalogued as COSV65573618; called by muse, mutect2
- PCDH10 | c.2487C>A p.S829= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV52091098; called by muse, mutect2
- PCDHA5 | c.2208C>A p.P736= | Silent (SNP) | VAF 15/89 reads (17%) | called by muse, mutect2, varscan2
- PCDHGA3 | c.1779G>A p.A593= | Silent (SNP) | VAF 24/150 reads (16%) | catalogued as COSV53928592; called by muse, mutect2, varscan2
- PHETA1 | c.96G>T p.A32= | Silent (SNP) | VAF 6/43 reads (14%) | called by muse, mutect2, varscan2
- PNPLA6 | c.2436G>T p.P812= (on ENST00000414982 / NM_001166111.2; = p.P764= on NM_006702.5) | Silent (SNP) | VAF 19/166 reads (11%) | catalogued as rs779055692; called by muse, mutect2, varscan2
- RAPGEF6 | c.4179T>C p.H1393= | Silent (SNP) | VAF 41/277 reads (15%) | catalogued as rs760749491; called by muse, mutect2, varscan2
- SGIP1 | c.2088T>C p.C696= | Silent (SNP) | VAF 32/374 reads (9%) | called by muse, mutect2
- SLC22A12 | c.1554C>A p.T518= | Silent (SNP) | VAF 20/224 reads (9%) | called by muse, mutect2
- SLC28A2 | c.990C>A p.L330= | Silent (SNP) | VAF 18/115 reads (16%) | called by muse, mutect2, varscan2
- STAT1 | c.1992G>A p.L664= | Silent (SNP) | VAF 32/374 reads (9%) | called by muse, mutect2
- UBQLNL | c.993C>G p.V331= | Silent (SNP) | VAF 20/338 reads (6%) | called by muse, mutect2
- USP29 | c.2595A>T p.S865= | Silent (SNP) | VAF 56/204 reads (27%) | called by muse, mutect2, varscan2
- VAC14 | c.1422A>G p.A474= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as rs746275730, COSV55757145; called by mutect2, varscan2
- XKR4 | c.27G>A p.L9= | Silent (SNP) | VAF 10/198 reads (5%) | called by muse, mutect2
- ZFC3H1 | c.186G>C p.R62= | Silent (SNP) | VAF 10/122 reads (8%) | called by muse, mutect2
- ZNF468 | c.810T>G p.P270= | Silent (SNP) | VAF 37/204 reads (18%) | called by muse, mutect2, varscan2
- ZNF729 | c.1365T>G p.T455= | Silent (SNP) | VAF 20/229 reads (9%) | called by muse, mutect2
- AC107023.1 | n.25+5564C>G | Intron (SNP) | VAF 61/375 reads (16%) | called by muse, mutect2, varscan2
- C2CD6 | c.1581+1883G>C | Intron (SNP) | VAF 6/128 reads (5%) | called by muse, mutect2
- CCDC110 | c.10+94G>A | Intron (SNP) | VAF 6/42 reads (14%) | called by muse, varscan2
- CHRND | c.*670C>A | 3'UTR (SNP) | VAF 40/374 reads (11%) | catalogued as rs1261942800; called by muse, mutect2, varscan2
- CTDSP1 | c.68-656C>T | Intron (SNP) | VAF 18/112 reads (16%) | catalogued as rs1038473414; called by muse, mutect2, varscan2
- DCHS2 | n.4615C>A | RNA (SNP) | VAF 7/92 reads (8%) | called by muse, mutect2
- ENDOV | chr17:80415095 C>A | 5'Flank (SNP) | VAF 6/100 reads (6%) | called by muse, mutect2
- GABRA1 | c.256-36A>T | Intron (SNP) | VAF 32/227 reads (14%) | catalogued as rs934802453; called by muse, mutect2, varscan2
- GLYATL1 | c.-144A>C | 5'UTR (SNP) | VAF 15/168 reads (9%) | called by muse, mutect2
- HPS4 | c.502-14C>T | Intron (SNP) | VAF 26/240 reads (11%) | called by muse, mutect2
- IZUMO3 | chr9:24545935 C>A | 5'Flank (SNP) | VAF 46/256 reads (18%) | called by muse, mutect2, varscan2
- KITLG | c.*69G>A | 3'UTR (SNP) | VAF 11/150 reads (7%) | called by muse, mutect2
- LINC02817 | n.255T>A | RNA (SNP) | VAF 32/265 reads (12%) | called by muse, mutect2, varscan2
- MIRLET7A3 | chr22:46112725 G>A | 5'Flank (SNP) | VAF 29/156 reads (19%) | catalogued as rs746391605; called by muse, mutect2, varscan2
- PAQR5 | c.513-226C>T | Intron (SNP) | VAF 24/250 reads (10%) | called by muse, mutect2
- RAP1GDS1 | c.509-4466A>G | Intron (SNP) | VAF 9/166 reads (5%) | catalogued as rs1364278930; called by muse, mutect2
- RNF212 | c.247-2954C>A | Intron (SNP) | VAF 10/82 reads (12%) | called by muse, mutect2, varscan2
- RPS4XP21 | n.442C>A | RNA (SNP) | VAF 34/188 reads (18%) | called by muse, mutect2, varscan2
- RRM2 | chr2:10122730 G>T | 5'Flank (SNP) | VAF 13/66 reads (20%) | called by muse, mutect2, varscan2
- SLC4A3 | c.812-662A>G | Intron (SNP) | VAF 7/29 reads (24%) | called by muse, mutect2
- SLC7A5P2 | n.137T>A | RNA (SNP) | VAF 16/106 reads (15%) | called by muse, mutect2, varscan2
- TTN | c.10361-4293G>C | Intron (SNP) | VAF 9/126 reads (7%) | called by muse, mutect2
- TXK | c.*2C>A | 3'UTR (SNP) | VAF 22/248 reads (9%) | called by muse, mutect2
- VIM | c.1229+20A>G | Intron (SNP) | VAF 24/215 reads (11%) | catalogued as rs749382642; called by muse, mutect2, varscan2
- ZBBX | c.2138-5997C>A | Intron (SNP) | VAF 36/272 reads (13%) | called by muse, mutect2, varscan2
- ZEB2 | c.73+4721A>G | Intron (SNP) | VAF 30/184 reads (16%) | called by muse, mutect2, varscan2
- ZNF849P | n.1391G>T | RNA (SNP) | VAF 17/224 reads (8%) | called by muse, mutect2
